Somatic mutation profile of tumor specimen 0DEA0R from CCDI case PBBPPV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.0 years (5,827 days).
Specimen 0DEA0R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c00d0411-7974-4947-8c9c-1226cec7988d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEA0M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3847f6a5-55ea-483f-acf4-d3f2b9a8c237

The open-access MAF lists 37 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, 5'Flank 2, Nonsense Mutation 2, Frame Shift Ins 2, 3'UTR 2, Frame Shift Del 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.4831C>T p.R1611* | Nonsense Mutation (SNP) | VAF 335/484 reads (69%) | catalogued as rs1554236040, COSV51670259; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.100G>C p.G34R | Missense Mutation (SNP) | VAF 269/699 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTB | c.1033A>G p.I345V | Missense Mutation (SNP) | VAF 228/890 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.272); catalogued as COSV59316513, COSV59319898; called by muse, mutect2, varscan2
- ARHGEF19 | c.1397A>G p.Y466C | Missense Mutation (SNP) | VAF 363/842 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779025536; called by muse, mutect2, varscan2
- CPNE7 | c.1850C>T p.P617L | Missense Mutation (SNP) | VAF 275/676 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs750312872, COSV99254433; called by muse, mutect2, varscan2
- CSMD1 | c.2090A>T p.E697V (on ENST00000520002; = p.E696V on NM_033225.6) | Missense Mutation (SNP) | VAF 35/989 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs1222783445; called by muse, mutect2
- DDX3X | c.1598G>A p.R533H (on ENST00000399959; = p.R534H on NM_001356.5) | Missense Mutation (SNP) | VAF 378/471 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as CM158021, COSV67863295; called by muse, mutect2, varscan2
- DISP3 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 259/721 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs773359901; called by muse, mutect2, varscan2
- HLTF | c.2327C>T p.A776V | Missense Mutation (SNP) | VAF 218/549 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1183071645; called by muse, mutect2, varscan2
- KCND3 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 281/722 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56175327; called by muse, mutect2, varscan2
- KIF2B | c.369C>A p.N123K | Missense Mutation (SNP) | VAF 198/522 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.104); catalogued as rs755087980; called by muse, mutect2, varscan2
- MBTPS1 | c.3083C>T p.P1028L | Missense Mutation (SNP) | VAF 42/988 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs1372724887, COSV58570867; called by muse, mutect2
- MED16 | c.1712C>T p.T571M | Missense Mutation (SNP) | VAF 140/550 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs770160006; called by muse, mutect2, varscan2
- PTPRQ | c.2648G>A p.R883Q (on ENST00000616559; = p.R841Q on NM_001145026.2) | Missense Mutation (SNP) | VAF 231/643 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs748192361; called by muse, mutect2, varscan2
- PTPRT | c.2248G>A p.V750M | Missense Mutation (SNP) | VAF 409/1350 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs372713520, COSV61961422, COSV61995720; called by muse, mutect2, varscan2
- SETD5 | c.3172dup p.Q1058Pfs*22 | Frame Shift Ins (INS) | VAF 200/522 reads (38%) | catalogued as rs1197870764; called by mutect2, varscan2
- AC126283.2 | c.268A>T p.S90C | Missense Mutation (SNP) | VAF 66/1131 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DLG2 | c.446G>T p.W149L (on ENST00000650630 / NM_001351274.2; = p.W112L on NM_001142699.3) | Missense Mutation (SNP) | VAF 248/724 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM83C | c.1951C>A p.P651T | Missense Mutation (SNP) | VAF 352/603 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- FLG | c.7568C>A p.S2523* | Nonsense Mutation (SNP) | VAF 120/319 reads (38%) | called by muse, mutect2, varscan2
- SP5 | c.601_610del p.A201Ffs*110 | Frame Shift Del (DEL) | VAF 106/311 reads (34%) | called by mutect2, varscan2
- TNRC18 | c.7520_7521dup p.A2508Rfs*294 | Frame Shift Ins (INS) | VAF 100/258 reads (39%) | called by mutect2, varscan2
- UBE2A | c.39C>A p.F13L | Missense Mutation (SNP) | VAF 394/467 reads (84%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS3 | c.321T>G p.V107= | Silent (SNP) | VAF 268/821 reads (33%) | called by muse, mutect2, varscan2
- CATIP | c.987C>T p.S329= | Silent (SNP) | VAF 217/577 reads (38%) | catalogued as COSV56822529; called by muse, mutect2, varscan2
- CCDC185 | c.123C>T p.T41= | Silent (SNP) | VAF 179/424 reads (42%) | catalogued as rs911176261, COSV100838767; called by muse, mutect2, varscan2
- FLNC | c.5760G>A p.P1920= | Silent (SNP) | VAF 174/417 reads (42%) | catalogued as rs375912712; ClinVar: likely benign; called by muse, mutect2, varscan2
- H2AC15 | c.66G>T p.A22= | Silent (SNP) | VAF 243/640 reads (38%) | catalogued as COSV100357067; called by muse, mutect2, varscan2
- KIF14 | c.1626C>T p.Y542= | Silent (SNP) | VAF 184/593 reads (31%) | catalogued as rs148834478; called by muse, mutect2, varscan2
- TMEM272 | c.231G>A p.R77= | Silent (SNP) | VAF 275/680 reads (40%) | called by muse, mutect2, varscan2
- WDR93 | c.951G>A p.Q317= | Silent (SNP) | VAF 305/689 reads (44%) | called by muse, mutect2, varscan2
- CCT2 | c.*47G>T | 3'UTR (SNP) | VAF 246/641 reads (38%) | called by muse, mutect2, varscan2
- IZUMO3 | c.-2A>T | 5'UTR (SNP) | VAF 153/380 reads (40%) | called by muse, mutect2, varscan2
- OAS3 | chr12:112938456 G>A | 5'Flank (SNP) | VAF 36/64 reads (56%) | catalogued as rs759640403; called by muse, varscan2
- OAZ3 | chr1:151762906 G>A | 5'Flank (SNP) | VAF 60/150 reads (40%) | catalogued as rs1553277314; called by muse, mutect2
- WTIP | c.*4984C>T | 3'UTR (SNP) | VAF 32/82 reads (39%) | catalogued as rs757473173; called by muse, mutect2, varscan2
- WWP2 | c.1594-58G>A | Intron (SNP) | VAF 44/135 reads (33%) | catalogued as rs990152878, COSV63126882; called by muse, mutect2, varscan2
